Gene-level copy-number profile of tumor specimen TCGA-LN-A9FR-01A from TCGA case TCGA-LN-A9FR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.2 years (25,657 days).
Specimen TCGA-LN-A9FR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ec9d3066-4083-4d65-9045-b4b29100364b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A9FR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/166d81ad-0d13-4646-8758-2165b31493c7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 1,810; copy number 2: 21,069; copy number 3: 14,085; copy number 4: 20,031; copy number 5: 895; copy number 6: 1,302; copy number 7: 405; copy number 8: 111.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A9FR-01A-11D-A386-01): tumor purity 0.56, ploidy 1.58, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,272,309–11,557,665, 1 gene (within-gene range 0–2): ATG7.
- chr3:11,488,300–11,529,755, 2 genes: AC026185.1, AC022001.1.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,786,927–27,529,814, 100 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 891. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
